Surgical pathology report (de-identified scan), TCGA case TCGA-B9-4114, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-4114-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Surgical Pathology Report

Accession #:

Diagnosis:

Kidney, left, radical nephrectomy

Histologic tumor type/subtype: Papillary renal cell carcinoma with necrosis

Histologic grade (if applicable): Fuhrman grade 3

Tumor size (greatest dimension): Multi-focal, largest focus is 22 cm in greatest dimension

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: Negative for tumor; the capsule is focally thinned, but intact

Gerota' s fascia: Negative for tumor

Renal vein: Negative for tumor

Ureter: Negative for tumor

Venous (large vessel) Negative for tumor

Lymphatic (small vessel): Present

Histologic assessment of surgical margins:

Perirenal adipose tissue: Negative for tumor; closest perirenal adipose tissue margin at area of focally thinned capsule is 1 mm (A5).

Gerota' s fascia: Negative for tumor

Renal vein: Negative for tumor

Renal artery: Negative for tumor

Ureter: Negative for tumor

[page 2 of 4]
Adrenal gland: Not present

Lymph nodes: Not identified grossly

Other significant findings: Focal glomerulosclerosis

AJCC Staging:

pT2

pNx

pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

with a clinical history of a large left renal mass, now undergoing left radical nephrectomy. [REDACTED], the patient has known papillary renal cell carcinoma.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left kidney."

Specimen fixation: formalin

Type of specimen: radical nephrectomy

Side of specimen: left

Size and weight of specimen: 2,370 grams; 22 x 17 x 12 cm

Orientation: Inking: exterior surface=black

Presence/absence of adrenal gland: absent

Tumor description/site: Tumor effaces and expands almost the entire kidney parenchyma.

Tumor size: 22 x 15 x 12 cm

Presence/absence of multicentricity: multicentric with at least very large abutting masses and several peripheral satellite masses; the largest masses are at least 10 cm in

[page 3 of 4]
greatest dimension each

Confinement/non-confinement to the kidney: tumor appears to abut, but does not extend through the renal capsule

NOTE: Upon receipt in the gross room, an approximately 4.5 cm defect on the exterior surface of the specimen is noted, through which tumor extrudes. This site is inked yellow.

Extent of invasion:

Perirenal adipose tissue: tumor grossly does not involve

Gerota' s fascia: tumor grossly does not involve

Renal vein: tumor grossly does not involve

Ureter: tumor grossly does not involve

Other organs: not applicable

Surgical margins:

Perirenal adipose tissue: grossly negative

Renal vein: grossly negative

Renal artery: grossly negative

Ureter: grossly negative

Description of kidney away from tumor: Compressed, but grossly unremarkable.

Lymph nodes (hilar): not identified

Other significant findings: none

Tissue submitted for special investigations: normal and tumor sample tissue provided to Tissue Procurement.

Digital photograph taken: not taken

Block Summary:

(Inking: exterior surface=black, area of defects noted (as described above) upon receipt in the gross room=yellow)

A1 - hilar vascular and ureteral margins, en face

A2 - additional sampling of hilum

A3 - tumor

A4 - tumor, possibly involving collecting system

A5 - tumor, ?extracapsular extension

A6 - tumor, ?extracapsular extension (adjacent to A5)

A7 - tumor, ?extracapsular extension (adjacent to A6)

A8 - tumor, site of defect noted on exterior surface at time of receipt

A9 - tumor interface with normal kidney

[page 4 of 4]
A10 - tumor, two non-adjacent sections
A11 - tumor with perinephric fat
A12 - tumor with perinephric fat
A13 - additional tumor, abutting capsule
A14 - additional tumor, abutting capsule, adjacent to A13
A15 - tumor, center of one dominant mass
A16 - tumor, center of other dominant mass
A17,A18 - grossly normal appearing renal parenchyma
A19,A20 - perirenal adipose tissue

Source: NCI Genomic Data Commons file 0cb4d170-dbe0-4ae3-8bb6-fa238e75742a (TCGA-B9-4114.F823D83F-3FFC-4AB3-94D7-1212F193445F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).